Somatic mutation profile of tumor specimen MMRF_1260_1_BM_CD138pos (aliquot MMRF_1260_1_BM_CD138pos_T1_KAS5U_L01220) from MMRF case MMRF_1260, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 84.3 years (30,777 days).
Specimen MMRF_1260_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 246fb97e-1f46-48a9-8c59-849babac1470.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1260_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1260_1_PB_Whole_C2_KAS5U_L01232; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f028dd4-9d25-49a3-bb31-5e1022e3be40

The open-access MAF lists 77 somatic variants for this specimen: 29 protein-altering or splice-affecting, 10 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 21, Missense Mutation 17, Intron 11, Silent 10, Frame Shift Del 5, 5'UTR 3, Splice Site 2, 3'Flank 1, RNA 1, Nonstop Mutation 1, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.*1004A>G | 3'UTR (SNP) | VAF 19/131 reads (15%) | catalogued as rs78311289, CM002967, CM950476, COSV53390625, COSV53407424; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CPD | c.2990C>T p.A997V | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1449268016, COSV99852513; called by muse, mutect2, varscan2
- HOXD8 | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.219); catalogued as rs113257910; called by muse, mutect2, varscan2
- IGLL5 | c.205A>C p.R69= | Splice Region (SNP) | VAF 6/22 reads (27%) | catalogued as COSV73250240; called by muse, varscan2
- NAV2 | c.4822C>T p.R1608W (on ENST00000396087 / NM_001244963.2; = p.R1585W on NM_145117.5) | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs139431433; called by muse, mutect2, varscan2
- SNPH | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs771345502, COSV67871539; called by muse, mutect2, varscan2
- TMC7 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as rs766258887; called by muse, mutect2, varscan2
- VWA5A | c.1886G>A p.R629Q | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.048); catalogued as rs763551541, COSV64412797; called by muse, mutect2
- WDR75 | c.1796C>G p.S599C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV100134377, COSV100134467; called by muse, mutect2, varscan2
- ZNF646 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 83/188 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373725273; called by muse, mutect2, varscan2
- ABCC8 | c.4339_4340del p.D1447* | Frame Shift Del (DEL) | VAF 11/78 reads (14%) | called by mutect2, pindel, varscan2
- BTAF1 | c.850_872del p.E284Qfs*2 | Frame Shift Del (DEL) | VAF 17/43 reads (40%) | called by mutect2, pindel, varscan2
- CARD10 | c.818_819insAAAGGA p.K272_E273dup | In Frame Ins (INS) | VAF 45/102 reads (44%) | called by mutect2, varscan2
- CRACR2B | c.245T>C p.F82S | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- DMP1 | c.911C>T p.T304I | Missense Mutation (SNP) | VAF 85/143 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- FCGBP | c.7044C>A p.D2348E | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- IGLV3-1 | c.113_134del p.S38Nfs*47 | Frame Shift Del (DEL) | VAF 24/80 reads (30%) | called by pindel, varscan2
- LSM4 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 62/200 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- MMS19 | c.246del p.L82Ffs*10 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- OR2Z1 | c.451G>T p.V151L | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PEX2 | c.917A>T p.*306Lext*15 | Nonstop Mutation (SNP) | VAF 20/142 reads (14%) | called by muse, mutect2, varscan2
- PHKB | c.1159G>T p.E387* | Nonsense Mutation (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2, varscan2
- PTPRU | c.3257+1G>T p.X1086_splice | Splice Site (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- RTF2 | c.335_336del p.D112Gfs*34 | Frame Shift Del (DEL) | VAF 47/132 reads (36%) | called by mutect2, pindel, varscan2
- RYR3 | c.9868C>T p.L3290F (on ENST00000389232; = p.L3291F on NM_001036.6) | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SETX | c.6379G>A p.A2127T | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC5A8 | c.1166-2A>G p.X389_splice | Splice Site (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- TAS2R19 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- ZNF248 | c.1700A>G p.Q567R | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.062); called by muse, mutect2
- ZNF318 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- APOB | c.2634C>A p.S878= | Silent (SNP) | VAF 47/95 reads (49%) | called by muse, mutect2, varscan2
- ART1 | c.675T>G p.L225= | Silent (SNP) | VAF 16/240 reads (7%) | catalogued as COSV51703109; called by muse, mutect2
- DST | c.20073A>G p.G6691= (on ENST00000361203 / NM_001374722.1; = p.G4388= on NM_015548.5) | Silent (SNP) | VAF 39/88 reads (44%) | catalogued as rs1452562947; called by muse, mutect2, varscan2
- HSPG2 | c.8937C>T p.H2979= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as rs1403978122; called by muse, mutect2, varscan2
- KLHL1 | c.1993C>A p.R665= | Silent (SNP) | VAF 6/9 reads (67%) | called by muse, mutect2, varscan2
- MTHFD1L | c.2424T>C p.A808= | Silent (SNP) | VAF 35/133 reads (26%) | called by muse, mutect2, varscan2
- MYH7 | c.2314C>T p.L772= | Silent (SNP) | VAF 50/110 reads (45%) | called by muse, mutect2, varscan2
- NLRP3 | c.3045G>A p.A1015= | Silent (SNP) | VAF 72/184 reads (39%) | catalogued as rs139995782, COSV100275227; called by muse, mutect2, varscan2
- SPI1 | c.693G>A p.A231= | Silent (SNP) | VAF 19/268 reads (7%) | catalogued as rs140748162; called by muse, mutect2
- SVEP1 | c.9960C>T p.N3320= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as rs781527818; called by muse, mutect2, varscan2
- ATP11C | c.*2211A>C | 3'UTR (SNP) | VAF 10/11 reads (91%) | called by muse, mutect2, varscan2
- CALN1 | c.*5282T>G | 3'UTR (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- CFAP20DC | c.1593+1880G>C | Intron (SNP) | VAF 5/51 reads (10%) | catalogued as rs984385694; called by muse, mutect2, varscan2
- CLEC7A | c.*1359T>G | 3'UTR (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- COL8A1 | c.*652A>G | 3'UTR (SNP) | VAF 31/95 reads (33%) | called by muse, mutect2, varscan2
- CYP27A1 | c.844+38G>A | Intron (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- DGKB | c.*852T>G | 3'UTR (SNP) | VAF 18/27 reads (67%) | called by muse, mutect2, varscan2
- DPYSL3 | c.*475G>A | 3'UTR (SNP) | VAF 50/171 reads (29%) | called by muse, mutect2, varscan2
- DSCAM | c.*1C>T | 3'UTR (SNP) | VAF 83/199 reads (42%) | called by muse, mutect2, varscan2
- DST | c.4297-884A>G | Intron (SNP) | VAF 9/16 reads (56%) | catalogued as rs1213773107; called by muse, mutect2, varscan2
- FAM177B | c.242-276G>A | Intron (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2, varscan2
- FKBP15 | c.*1588T>A | 3'UTR (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- GABRA1 | chr5:161899726 T>G | 3'Flank (SNP) | VAF 27/77 reads (35%) | called by muse, mutect2, varscan2
- HMGN2 | c.60+15C>A | Intron (SNP) | VAF 22/86 reads (26%) | called by muse, mutect2, varscan2
- IGHM | chr14:105859497 del CAGCCCAGCTCAGCC | 5'Flank (DEL) | VAF 12/13 reads (92%) | called by mutect2, varscan2
- IRAG2 | c.3912-32T>G | Intron (SNP) | VAF 33/86 reads (38%) | called by muse, mutect2, varscan2
- JKAMP | c.*436T>G | 3'UTR (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- KCNJ3 | c.*1807T>G | 3'UTR (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- LIPH | c.*1420_*1422del | 3'UTR (DEL) | VAF 5/45 reads (11%) | catalogued as rs201921693; called by pindel, varscan2
- MBOAT2 | c.*876G>A | 3'UTR (SNP) | VAF 33/89 reads (37%) | catalogued as rs777100504; called by muse, mutect2, varscan2
- MYZAP | c.*214C>T | 3'UTR (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- NTRK2 | c.1585+9231del | Intron (DEL) | VAF 4/11 reads (36%) | called by mutect2, varscan2
- OR52A1 | c.*512G>A | 3'UTR (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2
- PGRMC2 | c.419-102T>C | Intron (SNP) | VAF 7/11 reads (64%) | called by muse, varscan2
- PINX1 | c.*133C>T | 3'UTR (SNP) | VAF 12/25 reads (48%) | catalogued as rs1363904623; called by muse, mutect2, varscan2
- PSMG3-AS1 | n.3716G>A | RNA (SNP) | VAF 68/156 reads (44%) | catalogued as rs964251132; called by muse, mutect2, varscan2
- RNGTT | c.-146C>T | 5'UTR (SNP) | VAF 42/78 reads (54%) | catalogued as rs1431618540; called by muse, mutect2, varscan2
- SLC5A7 | c.*1584C>T | 3'UTR (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- SMOC2 | c.1323+859G>A | Intron (SNP) | VAF 44/88 reads (50%) | catalogued as rs1049748769; called by muse, mutect2, varscan2
- SPANXN2 | c.-42C>G | 5'UTR (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- SYNGR1 | c.*3011G>A | 3'UTR (SNP) | VAF 37/83 reads (45%) | catalogued as rs930499099; called by muse, mutect2, varscan2
- TBC1D13 | c.*1960A>T | 3'UTR (SNP) | VAF 61/130 reads (47%) | called by muse, mutect2, varscan2
- TMEM184A | c.*129G>A | 3'UTR (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- TOR3A | c.260-171C>T | Intron (SNP) | VAF 47/92 reads (51%) | called by muse, mutect2, varscan2
- TRDN | c.484+1681_484+1682del | Intron (DEL) | VAF 14/30 reads (47%) | catalogued as rs1360322084; called by pindel, varscan2
- TRIM32 | c.-68C>G | 5'UTR (SNP) | VAF 11/128 reads (9%) | catalogued as rs1463779799, COSV100528983; called by muse, mutect2
- ZNF721 | c.*1051T>C | 3'UTR (SNP) | VAF 24/59 reads (41%) | called by muse, mutect2, varscan2
